Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A43M, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A43M-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: [REDACTED]

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

Comments: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

Source of specimen: Distal esophagus, proximal stomach. History of a T2N0 distal esophagus cancer, pancreatic 2.3 cm lesion. History of colon cancer, hypertension, osteoarthritis, glaucoma bilaterally, left central retinal vein occlusion, hysterectomy, open chole, sigmoid colon and resection, cancer and dysphagia.

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Distal esophagus proximal stomach" Received in formalin in a large container is a 6.2 cm long portion of distal esophagus and an 11 x 3.5 x 1.1 cm proximal cuff of stomach. The adventitia is red-tan and unremarkable. The esophageal mucosa is gray-tan and predominantly folded. At the gastroesophageal gastric junction a focal area of granular tissue is identified. Underlying the esophagogastric junction an ill-defined 7.2 x 1.3 x 0.3 cm annular tumor is identified at the cardia of the stomach. There is possible some extension into the esophagus. The tumor is 5.5 cm away from the proximal margin and 1.8 cm away from the distal margin, tan-gray and granular. The distal margin is inked blue, the adventitia is inked black. Tumor has a maximum depth of 0.7 cm and extends to paraesophageal fat. Multiple possible lymph nodes are identified ranging up to 1.2 cm.

1A. Proximal margin, shave and submitted for frozen section.

Frozen section control.

1B-C. Distal margin, representative sections.

Frozen section control.

1D. Tumor to distal margin.

1E. Tumor to esophagogastric junction and adjacent proximal tissue.

1F-G. Tumor to deep.

1H. Tumor to esophagogastric junction.

1I. Multiple possible lymph nodes.

1J-M. One bisected lymph node. (

2. "New proximal margin, cervical esophageal margin" Received in formalin in a small container is a 1.2 cm long x 2.2 cm in diameter portion of esophagus. Submucosal hemorrhage is identified. No other abnormalities are noted.

FROZEN SECTION REPORT

1A. Proximal margin negative.

1B-C. Distal margin negative.

1CD-0-3

adenocarcinoma, NOS

8/40/13

site: esophagus, distal third

C15.5

8-20-12 RD

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3

SEX: [REDACTED]

PAT TYPE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

VERIFIED BY: [REDACTED]

ESOPHAGUS CARCINOMA

LOCATION: Lower

SIZE: 7.2 cm

TREATED WITH CHEMO/RADIATION THERAPY: No

TYPE OF CARCINOMA: Adenocarcinoma

DEPTH OF INVASION: Superficially into periesophageal adipose.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 4/8

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T3 N2

PROCEDURE: SPDIX

VERIFIED BY: [REDACTED]

1. Distal esophagus and proximal stomach, distal esophagectomy: Adenocarcinoma (7.2 cm), invading into adventitia/periesophageal adipose. Margins negative. Four of eight lymph nodes positive for metastatic adenocarcinoma. Please see template for details.

2. New cervical esophageal margin, excision: Negative for carcinoma.

Pathologic findings discussed with [REDACTED]

I, [REDACTED] the signing staff pathologist, have personally

Site approved by TCGA 8/9/12. *lw*

Diagnosis Discrepancy	CE	

Colon

8/9/12

Source: NCI Genomic Data Commons file 5149ffc8-f272-4325-9dfd-f510325570a7 (TCGA-L5-A43M.B8676218-180D-432D-A821-CDA5947B38FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).